Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7427, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7427-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS:

RIGHT ALVEOLECTOMY:

SQUAMOUS CARCINOMA FOCALLY INVADING INTO BONE; BONE MARGINS OF RESECTION FREE OF TUMOR.

(E) RIGHT INFERIOR TURBINATE:

Bone segments with attached mucosal and submucosal tissue; no tumor present.

COMMENT: This supplemental report is issued to give the diagnoses on specimens requiring decalcification. This report does not change any of the diagnoses given on the previous report.

SUPPLEMENTAL REPORT

DIAGNOSIS:

(A) RIGHT ALVEOLECTOMY:

SQUAMOUS CARCINOMA FOCALLY INVADING INTO BONE; BONE MARGINS OF RESECTION OF TUMOR.

(E) RIGHT INFERIOR TURBINATE:

Bone segments with attached mucosal and submucosal tissue, no tumor present.

COMMENT: This supplemental report is issued to give the diagnoses on specimens requiring decalcification. This report does not change any of the diagnoses given on the previous report.

DIAGNOSIS

[page 2 of 2]
-
- (A) RIGHT ALVEOLECTOMY:
INVASIVE WELL-DIFFERENTIATED SQUAMOUS CARCINOMA.
- (B) INFERIOR ANTERIOR MARGIN:
Squamous mucosa with mild to moderate dysplasia, no tumor present.
- (C) BUCCAL MARGIN:
Mild to moderate squamous dysplasia.
- (D) NASAL FLOOR MUCOSA:
Respiratory mucosa, no tumor present.
- (E) RIGHT INFERIOR TURBINATE:
Pending decalcification.
- (F) MAXILLARY SINUS MUCOSA:
Respiratory mucosa, no tumor present.
- (G) TOOTH:
Single tooth, gross only.
-

SPECIMEN

- (A) RIGHT ALVEOLECTOMY:
- (B) INFERIOR ANTERIOR MARGIN:
- (C) BUCCAL MARGIN:
- (D) NASAL FLOOR MUCOSA:
- (E) RIGHT INFERIOR TURBINATE:
- (F) MAXILLARY SINUS MUCOSA:
- (G) TOOTH:

SNOMED CODES

T-51004,M-80703

Source: NCI Genomic Data Commons file 486cd1e0-9934-4f46-95fb-23df1ed1ec44 (TCGA-CV-7427.F4564299-E702-4BBF-A9DB-C4B7BC3D54B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).